Somatic mutation profile of tumor specimen 0DTTXE from CCDI case PBCJWW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.8 years (645 days).
Specimen 0DTTXE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d64cee1-ce1e-4d9e-9ea9-bc3df82cdddb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTTX9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d6f1218-cc26-4264-b81e-0df93ec54166

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Splice Site 1, Silent 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C5AR2 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PPP1R10 | c.853+1G>A p.X285_splice | Splice Site (SNP) | VAF 130/966 reads (13%) | called by muse, mutect2, varscan2
- SUCLA2 | c.316A>T p.R106* | Nonsense Mutation (SNP) | VAF 145/1150 reads (13%) | called by muse, mutect2, varscan2
- MUC12 | c.12633C>A p.S4211= (on ENST00000379442; = p.S4068= on NM_001164462.1) | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, varscan2
